Somatic mutation profile of tumor specimen BA2856D (aliquot aq-BA2856D) from BEATAML1.0 case 2376, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.5 years (20,271 days).
Specimen BA2856D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81caa494-8298-4504-8c96-593f97e3c42f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2975D (Solid Tissue Normal), aliquot aq-BA2975D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/819068b3-1044-4515-bcd3-5793f36731fd

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, RNA 2, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 18/89 reads (20%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by pindel, varscan2
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 131/375 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS5 | c.2095G>A p.V699I | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs374203818; called by muse, mutect2, varscan2
- ELAPOR1 | c.2941C>T p.L981F | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100884395; called by muse, mutect2, varscan2
- KIF16B | c.3659G>A p.R1220H | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368296500; called by muse, mutect2, varscan2
- AFDN | c.2663C>A p.A888E | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.444); called by muse, mutect2
- ANKRD55 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.382); called by muse, mutect2
- ARMCX5-GPRASP2 | c.1579C>A p.H527N | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.453); called by muse, mutect2
- LRRC15 | c.1247G>A p.C416Y | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- RAD21 | c.1435A>T p.K479* | Nonsense Mutation (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- RBM6 | c.133G>C p.G45R | Missense Mutation (SNP) | VAF 77/174 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TMEM102 | c.440C>A p.P147Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UBXN10 | c.215_216del p.Y72* | Frame Shift Del (DEL) | VAF 25/83 reads (30%) | called by mutect2, pindel, varscan2
- USP33 | c.2684G>T p.G895V | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- ZNF331 | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ATL2 | c.1738T>C p.L580= | Silent (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- PLEC | c.1902G>A p.A634= (on ENST00000322810 / NM_201380.4; = p.A524= on NM_000445.5) | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs782376231, COSV59645312; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF587 | c.552A>G p.G184= | Silent (SNP) | VAF 69/214 reads (32%) | called by muse, mutect2, varscan2
- SNORD115-36 | n.73G>A | RNA (SNP) | VAF 50/174 reads (29%) | catalogued as rs765769885; called by muse, mutect2, varscan2
- SNORD115-44 | n.26G>A | RNA (SNP) | VAF 56/184 reads (30%) | catalogued as rs757391797; called by muse, mutect2, varscan2
